Somatic mutation profile of tumor specimen TCGA-US-A77G-01A (aliquot TCGA-US-A77G-01A-11D-A32N-08) from TCGA case TCGA-US-A77G, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 64.2 years (23,443 days).
Specimen TCGA-US-A77G-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6a47e94d-6585-482c-93ea-e59f1336d2db.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-US-A77G-11A (Solid Tissue Normal), aliquot TCGA-US-A77G-11A-11D-A32N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/19ca73d7-e178-48e6-bb73-ffcac16a24ca

The open-access MAF lists 35 somatic variants for this specimen: 26 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 21, Silent 9, Nonsense Mutation 2, Frame Shift Ins 1, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.148C>T p.Q50* | Nonsense Mutation (SNP) | VAF 246/960 reads (26%) | hotspot (GDC flag); catalogued as rs864622636, CM023895, COSV58683786; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 21/123 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1564_1565del p.P522Lfs*4 | Frame Shift Del (DEL) | VAF 81/390 reads (21%) | catalogued as rs377767374; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ATG9A | c.866G>A p.R289H | Missense Mutation (SNP) | VAF 32/150 reads (21%) | SIFT tolerated (0.76); PolyPhen probably damaging (0.957); catalogued as rs766744605, COSV63445179; called by muse, mutect2, varscan2
- CYTH4 | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 156/681 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.214); catalogued as rs766992258, COSV50636601; called by muse, mutect2, varscan2
- DSCAML1 | c.245G>A p.G82D (on ENST00000321322; = p.G22D on NM_020693.4) | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.854); catalogued as COSV100357286; called by mutect2, varscan2
- ENC1 | c.923A>T p.D308V | Missense Mutation (SNP) | VAF 67/366 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV56629906; called by muse, mutect2, varscan2
- FANCM | c.5104G>T p.D1702Y | Missense Mutation (SNP) | VAF 130/697 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.556); catalogued as COSV57507411; called by muse, mutect2, varscan2
- GLI3 | c.3151C>T p.R1051W | Missense Mutation (SNP) | VAF 76/323 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.676); catalogued as rs767681231, COSV67887518; called by muse, mutect2, varscan2
- GNS | c.1423T>C p.F475L | Missense Mutation (SNP) | VAF 177/802 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV50697018; called by muse, mutect2, varscan2
- KATNIP | c.191A>G p.H64R | Missense Mutation (SNP) | VAF 83/900 reads (9%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.891); catalogued as COSV99852035; called by muse, mutect2
- OXNAD1 | c.20T>G p.M7R | Missense Mutation (SNP) | VAF 177/835 reads (21%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.027); catalogued as rs778805458, COSV53269226; called by muse, mutect2, varscan2
- PCDH18 | c.2732T>A p.I911N | Missense Mutation (SNP) | VAF 200/977 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV61272645; called by muse, mutect2, varscan2
- PREX1 | c.4527G>T p.R1509S | Missense Mutation (SNP) | VAF 73/319 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV100906825; called by muse, mutect2, varscan2
- PSG7 | c.664C>A p.P222T | Missense Mutation (SNP) | VAF 409/2099 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.197); catalogued as rs531432163, COSV101343344; called by muse, mutect2, varscan2
- PTPN23 | c.3398C>T p.S1133F | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1275484478, COSV99651068; called by muse, mutect2, varscan2
- SCN5A | c.2065C>T p.R689C | Missense Mutation (SNP) | VAF 77/423 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as rs199473580, CM097648, COSV61141190; ClinVar: not provided; called by muse, mutect2, varscan2
- SCRIB | c.184C>T p.R62C | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57594233; called by muse, mutect2
- SPATA1 | c.893T>C p.L298P | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV55365129; called by muse, mutect2, varscan2
- TLR1 | c.721C>T p.Q241* | Nonsense Mutation (SNP) | VAF 48/211 reads (23%) | catalogued as COSV58305838; called by muse, mutect2, varscan2
- TMPRSS11E | c.487A>G p.K163E | Missense Mutation (SNP) | VAF 105/597 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0.202); catalogued as rs1157672822, COSV59521525; called by muse, mutect2, varscan2
- TRPC6 | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 136/716 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as rs778491013, COSV60252048; called by muse, mutect2, varscan2
- ZFP57 | c.667C>T p.R223C | Missense Mutation (SNP) | VAF 88/347 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.51); catalogued as rs758594645, COSV65305932; called by muse, mutect2, varscan2
- ZMIZ2 | c.2226C>G p.S742R | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.259); catalogued as COSV99537222; called by muse, mutect2, varscan2
- SPEF2 | c.1576_1582dup p.N528Tfs*16 | Frame Shift Ins (INS) | VAF 49/365 reads (13%) | called by mutect2, varscan2
- SRPK3 | c.1607_1621del p.T536_F541delinsI | In Frame Del (DEL) | VAF 111/364 reads (30%) | called by mutect2, pindel, varscan2
- ATP2B2 | c.1212C>T p.Y404= (on ENST00000352432; = p.Y370= on NM_001683.5) | Silent (SNP) | VAF 57/240 reads (24%) | catalogued as COSV59508647; called by muse, mutect2, varscan2
- DIAPH3 | c.1389G>A p.E463= (on ENST00000400324 / NM_001042517.2; = p.E200= on NM_030932.3) | Silent (SNP) | VAF 112/580 reads (19%) | catalogued as rs774832755, COSV57382826; ClinVar: likely benign; called by muse, mutect2, varscan2
- DNAH1 | c.2292C>T p.S764= | Silent (SNP) | VAF 56/259 reads (22%) | catalogued as COSV70237473; called by muse, mutect2, varscan2
- PCDHA7 | c.2040G>A p.S680= | Silent (SNP) | VAF 95/515 reads (18%) | catalogued as COSV65338721; called by muse, mutect2, varscan2
- PCDHA8 | c.123C>T p.H41= | Silent (SNP) | VAF 56/534 reads (10%) | catalogued as rs782285371, COSV100971043, COSV65335672; called by muse, varscan2
- PCDHGA8 | c.1497G>A p.A499= | Silent (SNP) | VAF 49/227 reads (22%) | catalogued as COSV99547263; called by muse, mutect2, varscan2
- PKD2L1 | c.1209C>T p.F403= | Silent (SNP) | VAF 50/252 reads (20%) | catalogued as rs768886570, COSV100559458; called by muse, mutect2, varscan2
- PRRG3 | c.597G>A p.A199= | Silent (SNP) | VAF 129/269 reads (48%) | catalogued as rs779479095, COSV64850858; called by muse, mutect2, varscan2
- TRIM67 | c.1665C>T p.A555= | Silent (SNP) | VAF 35/307 reads (11%) | catalogued as rs368294541, COSV100792210; called by muse, mutect2, varscan2
